Gene-level copy-number profile of tumor specimen ALCH-B505-TTP1-A from ALCHEMIST case ALCH-B505, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.0 years (20,446 days).
Specimen ALCH-B505-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 36923922-d28f-4922-b3c2-cea391704838.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B505-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/f83783da-0424-432e-814d-bbd46c9a96ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 684; copy number 2: 52,392; copy number 3: 5,106; copy number 4: 179; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,532,766–42,533,442, 1 gene (within-gene range 0–2): AC025750.1.
- chr3:125,816,082–125,816,286, 1 gene: SNRPCP11.
- chr4:185,018,841–185,020,804, 1 gene: HELT.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr15:76,993,359–77,037,475, 1 gene: PSTPIP1.
- chr15:77,043,680–77,045,160, 1 gene (within-gene range 0–2): AC090181.1.
- chr19:45,733,439–45,769,806, 3 genes (within-gene range 0–2): BHMG1, SIX5, AC074212.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,272,393–25,330,445, 2 genes, copy number 5 (within-gene range 4–5): RHD, SDHDP6.

Autosomal genes at a single copy (total copy number 1): 668. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
